Somatic mutation profile of tumor specimen ALCH-B2SA-TTP1-A (aliquot ALCH-B2SA-TTP1-A-2-0-D-A78Q-36) from ALCHEMIST case ALCH-B2SA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.0 years (22,272 days).
Specimen ALCH-B2SA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7db731b6-bd43-4148-8e7a-eacb20138ca9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SA-NB1-A (Blood Derived Normal), aliquot ALCH-B2SA-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea856e86-64a8-4fdc-b43e-6ef5c08f7243

The open-access MAF lists 549 somatic variants for this specimen: 379 protein-altering or splice-affecting, 108 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 339, Silent 108, Intron 29, Nonsense Mutation 24, RNA 13, 3'UTR 9, 5'UTR 6, Splice Site 6, Frame Shift Del 4, 3'Flank 4, Frame Shift Ins 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 169/1004 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs730882008, CM004344, COSV52689673, COSV52773873, COSV52969460, COSV53068318; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.579C>A p.S193R | Missense Mutation (SNP) | VAF 44/492 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757943582; called by muse, mutect2
- ABCB6 | c.2228A>G p.K743R | Missense Mutation (SNP) | VAF 93/471 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1208623912; called by muse, mutect2, varscan2
- ABCC12 | c.2630C>T p.T877I | Missense Mutation (SNP) | VAF 58/947 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754356403; called by muse, mutect2
- ABCC12 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 82/371 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs374228610, COSV100252371, COSV60912597; called by muse, mutect2, varscan2
- ACTRT2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 46/556 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs753334145; called by muse, mutect2
- ADGRE2 | c.714C>A p.C238* | Nonsense Mutation (SNP) | VAF 52/597 reads (9%) | catalogued as COSV100216332; called by muse, varscan2
- ADGRG4 | c.9136G>T p.A3046S | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV54948628; called by muse, mutect2, varscan2
- ANKRD30B | c.3748G>T p.A1250S | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1276832069; called by muse, mutect2
- ASTN1 | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 98/493 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV100705161; called by muse, mutect2, varscan2
- B3GALT1 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.592); catalogued as COSV59909611; called by muse, mutect2
- BMPR1A | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 72/830 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs1310807915; called by muse, mutect2
- CASR | c.2365C>T p.R789C (on ENST00000490131; = p.R866C on NM_000388.4) | Missense Mutation (SNP) | VAF 38/574 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CD121612, COSV99948414; called by muse, mutect2
- CATSPER1 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 85/481 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56411436; called by muse, mutect2, varscan2
- CATSPERB | c.3205G>A p.G1069R | Missense Mutation (SNP) | VAF 61/472 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1303094175; called by muse, mutect2, varscan2
- CCDC171 | c.3494G>T p.W1165L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV52641029; called by muse, mutect2
- CCN3 | c.308C>A p.T103K | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs751176923; called by muse, mutect2
- CD40LG | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as CM930090; called by muse, mutect2, varscan2
- CDH10 | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 59/1022 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52580048; called by muse, mutect2
- CDH18 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99933993; called by muse, mutect2, varscan2
- CENPL | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs759796518; called by muse, mutect2, varscan2
- CNTNAP2 | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as rs1402650519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 55/493 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99471067; called by muse, mutect2, varscan2
- COL27A1 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs781235729, COSV100620675; called by muse, mutect2
- COLEC11 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 44/599 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.155); catalogued as COSV52595437; called by muse, mutect2
- CPAMD8 | c.3754G>T p.A1252S (on ENST00000651564; = p.A1205S on NM_015692.5) | Missense Mutation (SNP) | VAF 61/353 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.33); catalogued as COSV71596602; called by muse, mutect2, varscan2
- CSMD1 | c.6241C>T p.Q2081* (on ENST00000520002; = p.Q2080* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 44/423 reads (10%) | catalogued as COSV59286954, COSV59289188; called by muse, varscan2
- CSMD3 | c.2972G>T p.R991L (on ENST00000297405 / NM_001363185.1; = p.R887L on NM_052900.3) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52168720; called by muse, mutect2
- DCHS1 | c.8672G>T p.R2891L | Missense Mutation (SNP) | VAF 107/384 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs60443131; called by muse, mutect2, varscan2
- DDX50 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as rs1372347407; called by muse, mutect2
- DDX55 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 54/481 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs764648878; called by muse, mutect2, varscan2
- DHRS7C | c.825G>T p.M275I (on ENST00000330255 / NM_001220493.2; = p.M274I on NM_001105571.3) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV57649838; called by muse, mutect2, varscan2
- DIP2C | c.895G>T p.G299W | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55160808; called by muse, mutect2
- DNAAF3 | c.991G>T p.G331W (on ENST00000524407 / NM_001256715.2; = p.G378W on NM_178837.4) | Missense Mutation (SNP) | VAF 123/619 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs7508641, COSV100787833, COSV61276050; called by muse, mutect2, varscan2
- DNAH7 | c.4797G>A p.M1599I | Missense Mutation (SNP) | VAF 75/479 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs1232179847, COSV56760098; called by muse, mutect2, varscan2
- DSEL | c.2383G>T p.V795L | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs374315429; called by muse, mutect2, varscan2
- DSPP | c.2500G>T p.D834Y | Missense Mutation (SNP) | VAF 151/1777 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56807689; called by muse, mutect2
- EYA2 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 38/732 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs770068078; called by muse, mutect2
- FAM171A1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 130/821 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65316829; called by muse, mutect2, varscan2
- FAM189A2 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 44/624 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV57384098; called by muse, mutect2
- FAM234B | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52193457; called by muse, mutect2, varscan2
- FAM91A1 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 38/509 reads (7%) | catalogued as rs1254946393; called by muse, mutect2
- FOXL2 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 71/502 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV57726404, COSV57729898; called by muse, mutect2, varscan2
- FSCB | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100469674; called by muse, mutect2, varscan2
- GABRB3 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 55/613 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1325124119, COSV54650674, COSV54680575; called by muse, mutect2
- GABRG3 | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 69/808 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.835); catalogued as COSV100406060; called by muse, mutect2
- GALC | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 49/732 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as CM163002, COSV99730327; called by muse, mutect2
- GALNT2 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 106/478 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs574340854; called by muse, mutect2, varscan2
- GATAD2B | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 153/806 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs1408392480; called by muse, mutect2, varscan2
- GIMAP1 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 70/466 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56188747; called by muse, mutect2, varscan2
- GPBP1L1 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV51967170; called by muse, mutect2, varscan2
- GPR158 | c.3575C>A p.A1192D | Missense Mutation (SNP) | VAF 62/533 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.084); catalogued as COSV100894125; called by muse, mutect2, varscan2
- GRID1 | c.1873G>T p.V625L | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs201449834; called by muse, mutect2
- HEPACAM2 | c.91G>T p.G31W (on ENST00000394468 / NM_001039372.4; = p.G19W on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59058427; called by muse, mutect2, varscan2
- HSPA12A | c.1849G>T p.G617W | Missense Mutation (SNP) | VAF 85/1232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65020853; called by muse, mutect2
- HTR3D | c.1228G>C p.E410Q (on ENST00000382489 / NM_001163646.2; = p.E235Q on NM_182537.3) | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV61915730; called by muse, mutect2, varscan2
- IGHV1-18 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 44/822 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.762); catalogued as rs189620273; called by muse, mutect2
- IGHV1OR15-9 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 60/655 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1258278371; called by muse, mutect2
- IL1RAPL1 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369272343; called by muse, mutect2, varscan2
- JAKMIP1 | c.834G>C p.Q278H | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99289756; called by muse, mutect2
- JHY | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 129/858 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1212177270; called by muse, mutect2, varscan2
- KALRN | c.5581G>T p.A1861S (on ENST00000360013 / NM_001024660.4; = p.A164S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/412 reads (18%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.994); catalogued as rs55755864; called by muse, mutect2, varscan2
- KCNA3 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs1557759771; called by muse, mutect2
- KCNH2 | c.1830G>C p.K610N | Missense Mutation (SNP) | VAF 84/586 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CM139888; called by muse, mutect2, varscan2
- KCNH7 | c.1031C>T p.T344I | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.106); catalogued as COSV59812289; called by muse, mutect2
- KEAP1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV50339578; called by muse, varscan2
- KHDRBS2 | c.277del p.E93Kfs*15 | Frame Shift Del (DEL) | VAF 41/300 reads (14%) | catalogued as COSV55429110; called by mutect2, pindel, varscan2
- KLHL20 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV52942577; called by muse, mutect2, varscan2
- KRTAP26-1 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.56); catalogued as COSV62128948; called by muse, mutect2, varscan2
- KRTAP4-2 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 76/1009 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs374053955, COSV66658662; called by muse, mutect2
- LCE1C | c.242G>T p.R81M | Missense Mutation (SNP) | VAF 54/702 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV64219173; called by muse, mutect2
- LPIN2 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 218/1022 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs779538504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRPAP1 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs920198660; called by muse, mutect2
- LRRC4C | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 46/484 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53423667; called by muse, mutect2
- LRRTM4 | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV69139172, COSV69140181; called by muse, mutect2
- MAB21L1 | c.899T>A p.L300Q | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59803506; called by muse, mutect2
- MAGT1 | c.152G>C p.R51T (on ENST00000618282 / NM_001367916.1; = p.R83T on NM_032121.5) | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV63783129; called by muse, mutect2, varscan2
- MAPK8IP1 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 52/620 reads (8%) | catalogued as rs868353161; called by muse, mutect2
- MLXIPL | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs868971099; called by muse, mutect2, varscan2
- MROH7 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 72/504 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as rs368337420; called by muse, mutect2, varscan2
- MYL3 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); catalogued as rs199474707, CM062895, CM1412322; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- NLGN1 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 71/468 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV100849959; called by muse, mutect2, varscan2
- OGDHL | c.2189G>T p.W730L | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1036718892, COSV100934479; called by muse, mutect2
- ONECUT3 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs1455086691; called by muse, mutect2, varscan2
- OR10G8 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 83/764 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.011); catalogued as COSV70908251; called by muse, mutect2, varscan2
- OR10S1 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73342995; called by muse, mutect2, varscan2
- OR11G2 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV62132294; called by muse, mutect2
- OR11G2 | c.460del p.A154Qfs*21 | Frame Shift Del (DEL) | VAF 76/635 reads (12%) | catalogued as COSV100640021; called by mutect2, pindel, varscan2
- OR11H12 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 50/523 reads (10%) | catalogued as COSV101612483; called by muse, mutect2, varscan2
- OR11L1 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 133/590 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63316066; called by muse, mutect2, varscan2
- OR2F1 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 24/136 reads (18%) | catalogued as COSV67331660, COSV67331693; called by muse, varscan2
- OR2T34 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 169/755 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs1348194250, COSV100170265; called by muse, mutect2, varscan2
- OR2W3 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 36/808 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831913; called by muse, mutect2
- OR2W3 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 144/768 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV100831609; called by muse, mutect2, varscan2
- OR4C6 | c.82G>C p.V28L | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV58603612; called by muse, mutect2, varscan2
- OR5H15 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV100736609; called by muse, mutect2
- OR6B1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 91/607 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); catalogued as rs1217664623, COSV68770427; called by muse, mutect2, varscan2
- PDE1C | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs755452839; called by muse, mutect2, varscan2
- PGAP4 | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 54/679 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1007368948, COSV66387412; called by muse, mutect2
- PIK3C2G | c.162C>G p.Y54* | Nonsense Mutation (SNP) | VAF 66/323 reads (20%) | catalogued as rs775670304; called by muse, mutect2, varscan2
- PLCL1 | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV70822660; called by muse, mutect2, varscan2
- PLPPR4 | c.1026C>A p.D342E | Missense Mutation (SNP) | VAF 33/416 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV64567132; called by muse, mutect2
- POTEG | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 66/644 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1391923146; called by muse, varscan2
- POTEG | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 98/2522 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as rs1162031910; called by muse, mutect2
- PRR22 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 28/115 reads (24%) | catalogued as COSV100288572; called by muse, mutect2, varscan2
- PSG7 | c.1082C>A p.P361Q | Missense Mutation (SNP) | VAF 145/911 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.769); catalogued as rs184944789, COSV68445003; called by muse, mutect2, varscan2
- RAB25 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as COSV63108741; called by muse, mutect2, varscan2
- RGS7 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 38/809 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202033477, COSV58554179; called by muse, mutect2
- SCN2A | c.5152G>T p.G1718* | Nonsense Mutation (SNP) | VAF 71/858 reads (8%) | catalogued as rs1553463525; called by muse, mutect2
- SEMG1 | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1405547790; called by muse, varscan2
- SLC16A1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 108/683 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.29); catalogued as rs754077369; called by muse, mutect2, varscan2
- SLC35A2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 93/494 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.208); catalogued as COSV54429387; called by muse, mutect2, varscan2
- SLC35D1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 98/1260 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs544752539; called by muse, mutect2
- SLITRK1 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65677114; called by muse, mutect2
- SLITRK2 | c.2031C>A p.H677Q | Missense Mutation (SNP) | VAF 79/317 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs200374760, COSV100157471; called by muse, mutect2, varscan2
- SPATA31D1 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 93/530 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV61198959; called by muse, mutect2, varscan2
- ST7 | c.1541G>T p.R514L | Missense Mutation (SNP) | VAF 89/561 reads (16%) | PolyPhen benign (0.007); catalogued as COSV100127906; called by muse, mutect2, varscan2
- SUCO | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55262155, COSV55267678; called by muse, mutect2, varscan2
- SZT2 | c.5134G>T p.G1712W (on ENST00000634258 / NM_001365999.1; = p.G1655W on NM_015284.4) | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.77); catalogued as COSV65173075; called by muse, mutect2, varscan2
- TAMALIN | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.046); catalogued as rs1352802067; called by muse, varscan2
- TARS2 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 101/753 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.175); catalogued as COSV60872737; called by muse, mutect2, varscan2
- THSD4 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 83/876 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763120009, COSV55971553; called by muse, mutect2
- TMEM132C | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV59419682; called by muse, mutect2, varscan2
- TP53 | c.955A>T p.K319* | Nonsense Mutation (SNP) | VAF 46/508 reads (9%) | catalogued as COSV52675685, COSV52909445; called by muse, mutect2
- TRPC4 | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 78/508 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58992688; called by muse, mutect2, varscan2
- TRPC6 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs752330361; called by muse, varscan2
- TRPM6 | c.3705G>T p.E1235D | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV100666715; called by muse, mutect2, varscan2
- UNC80 | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV55895448; called by muse, mutect2, varscan2
- USP42 | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1296416712, COSV100084367; called by muse, mutect2
- WIPF1 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 45/468 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.933); catalogued as rs371993338; called by muse, mutect2
- ZNF804A | c.3552C>A p.F1184L | Missense Mutation (SNP) | VAF 48/596 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV56464736; called by muse, mutect2
- ZNF804B | c.3446C>G p.T1149R | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60852616; called by muse, mutect2, varscan2
- AC025575.2 | n.180G>T | Splice Region (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- ACAN | c.2794C>A p.P932T | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ADAD2 | c.422C>A p.P141H (on ENST00000315906 / NM_001145400.2; = p.P213H on NM_139174.4) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADAMTS16 | c.2362G>C p.V788L | Missense Mutation (SNP) | VAF 116/984 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ADGRA2 | c.2524C>A p.L842M | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRE2 | c.715C>A p.R239S | Missense Mutation (SNP) | VAF 52/598 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); called by muse, varscan2
- ADGRV1 | c.15244C>A p.Q5082K | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AKAP6 | c.3445del p.D1149Mfs*8 | Frame Shift Del (DEL) | VAF 75/511 reads (15%) | called by mutect2, pindel, varscan2
- AMER2 | c.1433G>T p.C478F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.419); called by muse, mutect2
- AMOTL1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ANKRD30B | c.446G>T p.S149I | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD34B | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD6 | c.1336A>C p.K446Q | Missense Mutation (SNP) | VAF 64/362 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ANO3 | c.1261T>A p.L421I | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF28 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 99/605 reads (16%) | called by muse, mutect2, varscan2
- ASIC3 | c.1088C>G p.S363W | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ASL | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 136/701 reads (19%) | called by muse, mutect2, varscan2
- ATM | c.4983C>G p.H1661Q | Missense Mutation (SNP) | VAF 96/519 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BOD1L1 | c.8374G>T p.D2792Y | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- BPIFB6 | c.1148T>A p.L383Q | Missense Mutation (SNP) | VAF 132/425 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CACNA1B | c.2485C>A p.P829T | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CACNA1C | c.2980G>T p.V994L | Missense Mutation (SNP) | VAF 144/716 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CACNA1C | c.5028G>T p.E1676D | Missense Mutation (SNP) | VAF 118/520 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CAMSAP1 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 67/472 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CASD1 | c.228C>T p.I76= | Splice Region (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- CBLN2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 25/349 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- CBWD1 | c.588G>T p.L196F | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC150 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.571); called by muse, mutect2
- CCDC168 | c.15332C>A p.S5111* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- CDH18 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 151/704 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CDH7 | c.1171C>A p.Q391K | Missense Mutation (SNP) | VAF 37/469 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- CEACAM6 | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CECR2 | c.4261C>A p.Q1421K (on ENST00000342247 / NM_001290047.2; = p.Q1237K on NM_001290046.1) | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CENPQ | c.579A>C p.E193D | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.954); called by muse, mutect2
- CEP152 | c.4694G>T p.G1565V (on ENST00000380950 / NM_001194998.2; = p.G1509V on NM_014985.4) | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.238); called by muse, mutect2
- CEP290 | c.4247G>T p.R1416L | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CETN1 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 48/567 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- CFAP43 | c.3428C>A p.P1143H | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP61 | c.1842C>A p.Y614* | Nonsense Mutation (SNP) | VAF 62/406 reads (15%) | called by muse, mutect2, varscan2
- CHCHD1 | c.328A>T p.R110W | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COBL | c.2595C>A p.S865R | Missense Mutation (SNP) | VAF 111/739 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL19A1 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- COL5A2 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 46/597 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COLGALT2 | c.1586T>A p.M529K | Missense Mutation (SNP) | VAF 66/397 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- COMTD1 | c.113G>T p.W38L | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- COMTD1 | c.112T>A p.W38R | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COX6A2 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CPXM1 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPZ | c.950A>T p.Q317L (on ENST00000360986 / NM_001014447.3; = p.Q306L on NM_003652.3) | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- CRISPLD1 | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 23/230 reads (10%) | called by muse, mutect2
- CUL3 | c.2075G>T p.R692M | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CWH43 | c.1621C>A p.L541M | Missense Mutation (SNP) | VAF 72/521 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CX3CR1 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 84/877 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYFIP2 | c.2600T>A p.V867D (on ENST00000616178 / NM_001291722.2; = p.V842D on NM_014376.4) | Missense Mutation (SNP) | VAF 96/534 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CYP26B1 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 25/290 reads (9%) | called by muse, mutect2
- CYP26B1 | c.47C>G p.A16G | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- CYP39A1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DACH2 | c.605C>A p.P202Q | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- DDX3X | c.1493C>T p.A498V (on ENST00000399959; = p.A499V on NM_001356.5) | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DICER1 | c.5072C>G p.S1691C | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DMD | c.6031C>A p.L2011I | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAI2 | c.415G>C p.A139P | Missense Mutation (SNP) | VAF 181/832 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPT | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 123/766 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- E4F1 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ELAC2 | c.368-1G>T p.X123_splice | Splice Site (SNP) | VAF 32/504 reads (6%) | called by muse, mutect2
- EPB41L2 | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 85/506 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ERICH3 | c.1579C>G p.P527A | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM131C | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FAM240A | c.236C>A p.P79Q (on ENST00000444264; = p.P73Q on NM_001195442.2) | Missense Mutation (SNP) | VAF 42/526 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2
- FAT3 | c.5284G>C p.E1762Q | Missense Mutation (SNP) | VAF 45/405 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- FEZF2 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 38/534 reads (7%) | called by muse, mutect2
- FOXI3 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 43/671 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.077); called by muse, mutect2
- GABRG1 | c.953C>A p.T318K | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- GAPVD1 | c.3978C>G p.F1326L (on ENST00000394104; = p.F1335L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/548 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2
- GCM1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 96/702 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GIGYF1 | c.2916G>T p.Q972H | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GIMD1 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 111/628 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- GJC2 | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 40/737 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GK2 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GMNC | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- GNAS | c.1129G>C p.G377R | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GPLD1 | c.1184A>C p.H395P | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GPR149 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM8 | c.2038_2039insT p.G680Vfs*12 | Frame Shift Ins (INS) | VAF 33/205 reads (16%) | called by mutect2, pindel, varscan2
- GRXCR1 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- H2AC14 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- HDAC11 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2
- HDAC9 | c.2378G>T p.C793F | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- HEATR1 | c.4058T>G p.V1353G | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- HEATR1 | c.4057G>C p.V1353L | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2
- HERC2 | c.6760G>C p.V2254L | Missense Mutation (SNP) | VAF 54/596 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- HHIPL1 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- HS3ST4 | c.388del p.S130Afs*20 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by pindel*, varscan2
- HTR3A | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 65/437 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IGHV3-66 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 194/1158 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.019); called by muse, varscan2
- IGKV1-16 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 68/822 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- IGKV1D-8 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 76/982 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- IGLV5-37 | c.346A>T p.M116L | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF22 | c.1055C>A p.S352Y | Missense Mutation (SNP) | VAF 103/429 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL10RB | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 48/779 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- ILDR2 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); called by muse, mutect2
- ILF2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INPP5D | c.535G>C p.E179Q (on ENST00000445964 / NM_001017915.3; = p.E178Q on NM_005541.5) | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- IQCE | c.131-4C>T | Splice Region (SNP) | VAF 140/1053 reads (13%) | called by muse, mutect2, varscan2
- ITGA10 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ITIH5 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 135/973 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- KBTBD13 | c.565A>T p.T189S | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2
- KCNA6 | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 48/788 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- KCNA6 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 48/794 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2
- KCNJ4 | c.1254G>C p.E418D | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL40 | c.1318T>C p.F440L | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- LAMA1 | c.1961T>G p.I654S | Missense Mutation (SNP) | VAF 68/1162 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- LAMB4 | c.2113C>A p.L705M | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LCE4A | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LDB1 | c.180C>G p.H60Q (on ENST00000425280 / NM_001321612.2; = p.H24Q on NM_003893.5) | Missense Mutation (SNP) | VAF 50/605 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.239); called by muse, mutect2
- LEFTY2 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 86/369 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- LINC02448 | n.405+1G>T | Splice Site (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2
- LMBR1 | c.916-1G>T p.X306_splice | Splice Site (SNP) | VAF 41/260 reads (16%) | called by muse, mutect2, varscan2
- LNX1 | c.1560G>T p.M520I (on ENST00000263925 / NM_001126328.3; = p.M424I on NM_032622.2) | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP1B | c.5087A>T p.Q1696L | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- LRP2 | c.7628T>G p.V2543G | Missense Mutation (SNP) | VAF 70/666 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.136); called by muse, mutect2
- MACF1 | c.7241G>T p.G2414V | Missense Mutation (SNP) | VAF 67/449 reads (15%) | called by muse, mutect2, varscan2
- MAP2 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K4 | c.3449G>T p.R1150L | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMRN1 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 52/618 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); called by muse, mutect2
- MROH2B | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, varscan2
- MTA1 | c.1984A>T p.T662S | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- MTRES1 | c.658A>C p.K220Q | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- MUC16 | c.26260C>A p.P8754T | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYF5 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH2 | c.1775A>G p.N592S | Missense Mutation (SNP) | VAF 114/847 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MYOCD | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 47/548 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- N4BP2L2 | c.2534G>A p.G845E (on ENST00000674422; = p.G416E on NM_033111.4) | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- NAALAD2 | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 130/846 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- NCAM1 | c.2497G>A p.E833K (on ENST00000316851 / NM_181351.5; = p.E823K on NM_000615.7) | Missense Mutation (SNP) | VAF 85/689 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- NECTIN4 | c.1520dup p.H508Tfs*31 | Frame Shift Ins (INS) | VAF 148/842 reads (18%) | called by mutect2, pindel, varscan2
- NF1 | c.3139G>A p.D1047N | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NKAIN2 | c.613T>A p.Y205N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- NPIPB11 | c.2613G>A p.M871I | Missense Mutation (SNP) | VAF 159/2028 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.284); called by muse, varscan2
- NRG3 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2
- NSUN6 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- NTSR1 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- NUTM2F | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.344); called by mutect2, varscan2
- OR10G9 | c.350T>C p.M117T | Missense Mutation (SNP) | VAF 45/402 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR13F1 | c.591A>T p.L197F | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR2A14 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR2M2 | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- OR2M4 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 44/549 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.707); called by muse, mutect2
- OR2W3 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 36/808 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2Y1 | c.190T>A p.S64T | Missense Mutation (SNP) | VAF 101/552 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- OR4L1 | c.832A>T p.I278F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5R1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5W2 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 125/613 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- OR6P1 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI6 | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP4 | c.4307A>T p.Q1436L | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PATZ1 | c.189C>G p.S63R | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH19 | c.2988A>T p.E996D (on ENST00000373034 / NM_001184880.2; = p.E948D on NM_020766.3) | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PCLO | c.324dup p.G109Wfs*4 | Frame Shift Ins (INS) | VAF 41/274 reads (15%) | called by mutect2, pindel, varscan2
- PDE11A | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 56/609 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- PDP1 | c.1585G>A p.V529I | Missense Mutation (SNP) | VAF 32/467 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.041); called by muse, mutect2
- PEX14 | c.1097G>C p.R366P | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGLYRP2 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- PGRMC1 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PIP5K1C | c.717C>G p.N239K | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PLCB1 | c.1601C>A p.A534D | Missense Mutation (SNP) | VAF 64/710 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- PLEKHF1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PNLIPRP1 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- POU6F2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCG | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- PRR23C | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.266); called by muse, mutect2
- PRR27 | c.238A>T p.T80S | Missense Mutation (SNP) | VAF 66/582 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PTBP3 | c.886+1G>T p.X296_splice | Splice Site (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- PXDNL | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RAD18 | c.255G>T p.L85F | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- RAD54L2 | c.3514A>T p.S1172C | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- REG1B | c.390C>A p.S130R | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPRD1A | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RXFP3 | c.1211T>A p.L404Q | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RYR2 | c.12369G>T p.E4123D | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR3 | c.2039T>C p.L680P | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCARA3 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.373); called by muse, mutect2
- SCN10A | c.4730T>A p.L1577Q | Missense Mutation (SNP) | VAF 44/590 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SCP2 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 82/610 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SDHA | c.1018A>G p.R340G | Missense Mutation (SNP) | VAF 156/948 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC14L5 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 64/438 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SEC23IP | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); called by muse, mutect2
- SEMA3E | c.2275C>T p.L759F | Missense Mutation (SNP) | VAF 49/607 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2
- SH3TC1 | c.2677G>T p.A893S | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SHCBP1 | c.1532A>T p.K511M | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SHISA6 | c.1132C>A p.L378M (on ENST00000409168 / NM_001173461.1; = p.L429M on NM_207386.4) | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- SIN3A | c.848A>C p.H283P | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2
- SKAP1 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC37A2 | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 36/517 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC3A2 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SMCP | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 203/1413 reads (14%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX25 | c.934G>C p.A312P | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- SORCS3 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SP140 | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- SPAG16 | c.1049T>A p.L350H | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SPAM1 | c.1489A>T p.S497C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SPATA31A6 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 57/1383 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- SPRR1B | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 88/798 reads (11%) | called by muse, mutect2, varscan2
- SPTA1 | c.1780C>A p.L594I | Missense Mutation (SNP) | VAF 139/791 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SUSD2 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by mutect2, varscan2
- SVEP1 | c.8879C>A p.P2960H | Missense Mutation (SNP) | VAF 89/470 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SYT11 | c.440C>A p.T147N | Missense Mutation (SNP) | VAF 92/399 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TAAR8 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TAF1L | c.3697G>T p.E1233* | Nonsense Mutation (SNP) | VAF 74/828 reads (9%) | called by muse, mutect2
- TBC1D10A | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TBC1D32 | c.3286A>G p.T1096A | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TENM2 | c.39A>T p.R13S | Missense Mutation (SNP) | VAF 106/580 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TEX45 | c.1385C>G p.P462R | Missense Mutation (SNP) | VAF 52/430 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX47 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TIAM2 | c.2595C>A p.C865* | Nonsense Mutation (SNP) | VAF 40/311 reads (13%) | called by muse, mutect2, varscan2
- TMCO1 | c.461G>T p.G154V (on ENST00000612311 / NM_001256164.1; = p.G103V on NM_019026.6) | Missense Mutation (SNP) | VAF 173/899 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TMEM132B | c.1699C>A p.H567N | Missense Mutation (SNP) | VAF 35/439 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2
- TMEM175 | c.935C>G p.A312G | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM225B | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.955); called by muse, mutect2
- TMTC1 | c.2488G>T p.G830C (on ENST00000539277 / NM_001193451.2; = p.G722C on NM_175861.3) | Missense Mutation (SNP) | VAF 51/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFRSF10D | c.257-1G>T p.X86_splice | Splice Site (SNP) | VAF 28/249 reads (11%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.4524G>T p.R1508S | Missense Mutation (SNP) | VAF 118/426 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TPO | c.1948G>T p.G650W | Missense Mutation (SNP) | VAF 62/734 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRBV19 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 61/500 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIP6 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.175); called by muse, mutect2
- TSGA10IP | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 95/455 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TTBK1 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- UGGT2 | c.2665G>T p.A889S | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, varscan2
- UPF2 | c.2575-2A>T p.X859_splice | Splice Site (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- USH2A | c.12044C>A p.T4015N | Missense Mutation (SNP) | VAF 102/422 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.163); called by muse, varscan2
- VCAN | c.4067C>A p.P1356H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VGF | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- WSCD2 | c.267C>A p.Y89* | Nonsense Mutation (SNP) | VAF 105/676 reads (16%) | called by muse, mutect2, varscan2
- ZFHX3 | c.5831C>A p.A1944D | Missense Mutation (SNP) | VAF 38/467 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- ZFHX4 | c.4360G>T p.A1454S | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2
- ZFP91 | c.1609G>C p.G537R | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ZNF326 | c.47A>T p.Y16F | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF350 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 89/435 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF423 | c.574C>A p.H192N (on ENST00000563137 / NM_001379286.1; = p.H184N on NM_015069.4) | Missense Mutation (SNP) | VAF 46/685 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF479 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 98/654 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF530 | c.1397G>T p.S466I | Missense Mutation (SNP) | VAF 68/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF7 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 50/604 reads (8%) | called by muse, mutect2
- ZNF716 | c.700A>T p.I234F | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- ZNF91 | c.2039A>T p.H680L | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF99 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN9 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZZEF1 | c.5248G>T p.A1750S | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA13 | c.7362G>T p.T2454= | Silent (SNP) | VAF 58/284 reads (20%) | catalogued as rs377081983, COSV101447165; called by muse, mutect2, varscan2
- ADAM2 | c.1803C>T p.C601= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- ADGRF2 | c.141T>C p.S47= | Silent (SNP) | VAF 46/242 reads (19%) | called by muse, mutect2, varscan2
- ADGRG4 | c.60C>T p.I20= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- AGPAT4 | c.237G>T p.P79= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as COSV57243889; called by muse, mutect2, varscan2
- ALG5 | c.702A>T p.T234= | Silent (SNP) | VAF 23/380 reads (6%) | called by muse, mutect2
- AMOTL1 | c.636G>A p.G212= | Silent (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- ANKK1 | c.1068G>A p.L356= | Silent (SNP) | VAF 88/468 reads (19%) | catalogued as rs376825165; called by muse, mutect2, varscan2
- ASMT | c.750G>T p.L250= (on ENST00000381229; = p.L278= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/794 reads (10%) | called by muse, mutect2, varscan2
- BICRA | c.2040G>T p.G680= | Silent (SNP) | VAF 48/473 reads (10%) | catalogued as rs757107695; called by muse, mutect2
- BOD1L1 | c.8373G>C p.L2791= | Silent (SNP) | VAF 19/282 reads (7%) | catalogued as COSV99238628; called by muse, mutect2
- BRD9 | c.1227C>G p.L409= | Silent (SNP) | VAF 84/967 reads (9%) | catalogued as rs1233558979; called by muse, mutect2
- C12orf50 | c.429A>T p.T143= | Silent (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2, varscan2
- CASS4 | c.1695G>T p.V565= | Silent (SNP) | VAF 62/213 reads (29%) | called by muse, mutect2, varscan2
- CDCA7 | c.879A>T p.R293= (on ENST00000347703 / NM_145810.3; = p.R372= on NM_031942.5) | Silent (SNP) | VAF 70/508 reads (14%) | catalogued as COSV100143678; called by muse, mutect2, varscan2
- CLEC17A | c.1089T>C p.S363= | Silent (SNP) | VAF 34/426 reads (8%) | called by muse, mutect2
- CNOT1 | c.4197G>T p.R1399= | Silent (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- DAB1 | c.121C>A p.R41= | Silent (SNP) | VAF 98/753 reads (13%) | catalogued as COSV59728131; called by muse, mutect2, varscan2
- DCAF8L2 | c.1131C>G p.A377= | Silent (SNP) | VAF 44/272 reads (16%) | called by muse, mutect2, varscan2
- DDI1 | c.432C>A p.A144= | Silent (SNP) | VAF 59/345 reads (17%) | called by muse, mutect2, varscan2
- DOCK10 | c.1860T>A p.A620= | Silent (SNP) | VAF 31/352 reads (9%) | catalogued as COSV99290600; called by muse, mutect2
- DPYD | c.2571G>A p.V857= | Silent (SNP) | VAF 33/404 reads (8%) | called by muse, mutect2
- ESPN | c.420G>T p.L140= | Silent (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- EVC2 | c.2751G>A p.K917= | Silent (SNP) | VAF 90/1148 reads (8%) | called by muse, mutect2
- FAT3 | c.7635C>T p.L2545= | Silent (SNP) | VAF 41/484 reads (8%) | catalogued as rs974824041; called by muse, mutect2
- FATE1 | c.220C>A p.R74= | Silent (SNP) | VAF 51/174 reads (29%) | called by muse, mutect2, varscan2
- FCN1 | c.114G>T p.V38= | Silent (SNP) | VAF 62/621 reads (10%) | called by muse, mutect2, varscan2
- FOXG1 | c.1227G>A p.L409= | Silent (SNP) | VAF 90/1311 reads (7%) | catalogued as COSV100486954; called by muse, mutect2
- FOXQ1 | c.867G>T p.T289= | Silent (SNP) | VAF 32/224 reads (14%) | called by muse, mutect2, varscan2
- GAL | c.141C>T p.A47= | Silent (SNP) | VAF 60/279 reads (22%) | catalogued as rs367644530; called by muse, mutect2, varscan2
- GALC | c.1992T>C p.A664= | Silent (SNP) | VAF 48/734 reads (7%) | catalogued as rs763585644; called by muse, mutect2
- H2BC8 | c.240T>C p.R80= | Silent (SNP) | VAF 61/464 reads (13%) | catalogued as rs770940533; called by muse, mutect2, varscan2
- HABP2 | c.636G>A p.Q212= | Silent (SNP) | VAF 44/466 reads (9%) | catalogued as rs967245190; called by muse, mutect2
- HAS1 | c.18G>T p.A6= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV55788471; called by muse, mutect2
- HHIP | c.1836T>C p.C612= | Silent (SNP) | VAF 34/339 reads (10%) | called by muse, mutect2
- HK2 | c.1302G>T p.L434= | Silent (SNP) | VAF 92/543 reads (17%) | called by muse, mutect2, varscan2
- IGHV3-35 | c.294G>T p.L98= | Silent (SNP) | VAF 106/462 reads (23%) | called by muse, mutect2, varscan2
- ILF2 | c.843G>T p.L281= | Silent (SNP) | VAF 48/446 reads (11%) | called by muse, mutect2
- IRF2BPL | c.717G>T p.L239= | Silent (SNP) | VAF 35/231 reads (15%) | called by muse, mutect2, varscan2
- KEL | c.1209C>A p.A403= | Silent (SNP) | VAF 88/722 reads (12%) | catalogued as COSV62337039; called by muse, mutect2, varscan2
- KRT17 | c.1266C>T p.S422= | Silent (SNP) | VAF 72/608 reads (12%) | called by muse, mutect2, varscan2
- KRTAP10-1 | c.810C>A p.S270= | Silent (SNP) | VAF 60/308 reads (19%) | catalogued as COSV59956244; called by muse, mutect2, varscan2
- LAMA1 | c.3345C>A p.T1115= | Silent (SNP) | VAF 108/569 reads (19%) | called by muse, mutect2, varscan2
- LBX1 | c.744C>G p.G248= | Silent (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- LTB4R | c.888G>T p.A296= | Silent (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- MAML2 | c.1731C>T p.S577= | Silent (SNP) | VAF 174/1704 reads (10%) | catalogued as rs1430881358; called by muse, varscan2
- MAPK11 | c.525G>A p.A175= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as rs201347111; called by muse, mutect2
- MC4R | c.867A>T p.I289= | Silent (SNP) | VAF 42/491 reads (9%) | catalogued as COSV55353149; called by muse, mutect2
- MDC1 | c.4812C>A p.S1604= | Silent (SNP) | VAF 35/339 reads (10%) | catalogued as rs1210875326; called by muse, mutect2, varscan2
- MLPH | c.1197G>A p.Q399= | Silent (SNP) | VAF 44/497 reads (9%) | called by muse, mutect2
- MYCBP2 | c.2961A>G p.R987= (on ENST00000357337; = p.R1025= on NM_015057.5) | Silent (SNP) | VAF 32/346 reads (9%) | called by muse, mutect2
- MYH4 | c.5757C>A p.S1919= | Silent (SNP) | VAF 40/595 reads (7%) | called by muse, mutect2
- NAALAD2 | c.1296C>A p.L432= | Silent (SNP) | VAF 27/231 reads (12%) | called by muse, mutect2, varscan2
- NDST4 | c.651G>T p.G217= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as COSV52130107; called by muse, mutect2, varscan2
- NOC4L | c.87C>T p.N29= | Silent (SNP) | VAF 68/468 reads (15%) | called by muse, mutect2, varscan2
- OR10S1 | c.522C>A p.T174= | Silent (SNP) | VAF 30/489 reads (6%) | catalogued as COSV101602516; called by muse, mutect2
- OR1J4 | c.372G>T p.V124= | Silent (SNP) | VAF 65/320 reads (20%) | called by muse, mutect2, varscan2
- OR4C16 | c.792C>A p.P264= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV58941008; called by muse, mutect2, varscan2
- OR4N5 | c.423C>T p.C141= | Silent (SNP) | VAF 32/316 reads (10%) | catalogued as rs372623364, COSV61320196; called by muse, mutect2, varscan2
- OR6P1 | c.387C>A p.P129= | Silent (SNP) | VAF 14/309 reads (5%) | called by muse, mutect2
- P2RX5 | c.309G>T p.V103= | Silent (SNP) | VAF 76/413 reads (18%) | catalogued as rs759453136; called by muse, mutect2, varscan2
- PCDH11X | c.3540C>A p.A1180= | Silent (SNP) | VAF 306/1210 reads (25%) | called by muse, mutect2, varscan2
- PCDH17 | c.3126G>A p.A1042= | Silent (SNP) | VAF 30/336 reads (9%) | catalogued as rs534412507, COSV100931621, COSV100931767, COSV64975173; called by muse, mutect2
- PDCD11 | c.792G>T p.T264= | Silent (SNP) | VAF 40/543 reads (7%) | catalogued as rs1412060312; called by muse, mutect2
- PHYHIPL | c.936C>T p.T312= | Silent (SNP) | VAF 30/338 reads (9%) | catalogued as COSV53246059, COSV53252006; called by muse, mutect2
- PIWIL3 | c.2589G>A p.V863= | Silent (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- PYGL | c.213G>T p.T71= | Silent (SNP) | VAF 54/310 reads (17%) | called by muse, mutect2, varscan2
- RBM15 | c.2034C>T p.S678= | Silent (SNP) | VAF 48/744 reads (6%) | catalogued as rs1353239176; called by muse, mutect2
- RGS6 | c.747C>A p.L249= | Silent (SNP) | VAF 40/462 reads (9%) | called by muse, mutect2
- RPGR | c.1704C>T p.F568= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- RYR1 | c.12555G>A p.A4185= | Silent (SNP) | VAF 40/241 reads (17%) | catalogued as rs1442355076, COSV62108558; called by muse, mutect2, varscan2
- SALL1 | c.2397C>G p.P799= | Silent (SNP) | VAF 159/953 reads (17%) | catalogued as COSV99192358; called by muse, mutect2, varscan2
- SCP2D1 | c.408G>T p.V136= | Silent (SNP) | VAF 53/320 reads (17%) | called by muse, mutect2, varscan2
- SENP7 | c.909G>A p.K303= | Silent (SNP) | VAF 32/234 reads (14%) | called by muse, mutect2, varscan2
- SETBP1 | c.1926C>A p.P642= | Silent (SNP) | VAF 149/1490 reads (10%) | called by muse, mutect2, varscan2
- SLC39A12 | c.1812G>C p.L604= (on ENST00000377369 / NM_001145195.2; = p.L567= on NM_152725.3) | Silent (SNP) | VAF 53/321 reads (17%) | catalogued as rs758140022, COSV66197892; called by muse, mutect2, varscan2
- SLC39A4 | c.573G>A p.R191= (on ENST00000301305 / NM_001374839.1; = p.R166= on NM_017767.3) | Silent (SNP) | VAF 41/448 reads (9%) | catalogued as rs782577342; called by muse, mutect2
- SLC4A2 | c.342G>T p.P114= | Silent (SNP) | VAF 45/294 reads (15%) | catalogued as COSV100055406; called by muse, mutect2, varscan2
- SLC9A2 | c.48G>A p.P16= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as rs753700807, COSV52131255; called by muse, varscan2
- SMCR8 | c.1614A>T p.P538= | Silent (SNP) | VAF 149/903 reads (17%) | called by muse, mutect2, varscan2
- SORCS1 | c.2808C>T p.T936= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as rs1415656734; called by muse, mutect2, varscan2
- SPATA18 | c.1308C>A p.P436= | Silent (SNP) | VAF 61/374 reads (16%) | called by muse, mutect2, varscan2
- SPHKAP | c.417C>G p.L139= | Silent (SNP) | VAF 36/216 reads (17%) | catalogued as COSV100763730; called by muse, mutect2, varscan2
- SPTA1 | c.4500C>T p.A1500= | Silent (SNP) | VAF 105/738 reads (14%) | catalogued as COSV63759495; called by muse, mutect2, varscan2
- SPTBN5 | c.5064G>T p.T1688= | Silent (SNP) | VAF 22/384 reads (6%) | called by muse, mutect2
- SRGAP2 | c.3180C>T p.S1060= (on ENST00000624873 / NM_001170637.4; = p.S1061= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/158 reads (28%) | catalogued as rs781947479; called by muse, mutect2, varscan2
- SULF1 | c.291G>T p.G97= | Silent (SNP) | VAF 120/778 reads (15%) | called by muse, mutect2, varscan2
- SV2C | c.363G>A p.R121= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as rs531923650; called by muse, mutect2, varscan2
- SVEP1 | c.8880T>A p.P2960= | Silent (SNP) | VAF 94/482 reads (20%) | called by muse, mutect2, varscan2
- TBC1D2 | c.447G>C p.P149= | Silent (SNP) | VAF 31/287 reads (11%) | called by muse, mutect2
- TBX2 | c.1011G>T p.P337= | Silent (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- TCHHL1 | c.1797A>C p.T599= | Silent (SNP) | VAF 135/603 reads (22%) | called by muse, mutect2, varscan2
- TECPR1 | c.1131G>T p.A377= | Silent (SNP) | VAF 57/400 reads (14%) | catalogued as COSV65784099; called by muse, mutect2, varscan2
- TMEM229A | c.147C>A p.A49= | Silent (SNP) | VAF 47/258 reads (18%) | called by muse, mutect2, varscan2
- TMEM52B | c.126C>G p.L42= (on ENST00000381923 / NM_001079815.1; = p.L22= on NM_153022.4) | Silent (SNP) | VAF 35/277 reads (13%) | called by muse, mutect2, varscan2
- TP53TG5 | c.711C>T p.R237= | Silent (SNP) | VAF 36/460 reads (8%) | called by muse, mutect2
- TPO | c.513G>T p.T171= | Silent (SNP) | VAF 88/937 reads (9%) | called by muse, mutect2
- TRPM1 | c.1986G>T p.V662= | Silent (SNP) | VAF 46/562 reads (8%) | called by muse, mutect2
- UBE2F | c.432C>T p.N144= | Silent (SNP) | VAF 18/291 reads (6%) | called by muse, mutect2
- UBR4 | c.13863G>A p.P4621= | Silent (SNP) | VAF 102/591 reads (17%) | catalogued as rs540655585, COSV100920401, COSV64391014; called by muse, mutect2, varscan2
- UNC80 | c.3190C>A p.R1064= | Silent (SNP) | VAF 98/774 reads (13%) | called by muse, mutect2, varscan2
- VCAM1 | c.237G>T p.T79= | Silent (SNP) | VAF 63/436 reads (14%) | catalogued as COSV99658470; called by muse, mutect2, varscan2
- VWF | c.6483C>G p.A2161= | Silent (SNP) | VAF 232/972 reads (24%) | called by muse, mutect2, varscan2
- YY2 | c.669G>A p.G223= | Silent (SNP) | VAF 70/334 reads (21%) | catalogued as rs776241984; called by muse, mutect2, varscan2
- ZBTB5 | c.1521C>T p.S507= | Silent (SNP) | VAF 41/369 reads (11%) | called by muse, mutect2, varscan2
- ZBTB7B | c.6G>T p.G2= (on ENST00000292176; = p.G36= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV52694877; called by muse, varscan2
- ZFHX4 | c.6330C>G p.T2110= | Silent (SNP) | VAF 40/494 reads (8%) | called by muse, mutect2
- ZSCAN9 | c.1131A>T p.R377= | Silent (SNP) | VAF 37/273 reads (14%) | called by muse, mutect2, varscan2
- AC021218.1 | n.350G>T | RNA (SNP) | VAF 57/430 reads (13%) | called by muse, mutect2, varscan2
- AC114741.1 | n.200G>T | RNA (SNP) | VAF 79/483 reads (16%) | called by muse, mutect2, varscan2
- ADK | c.66-23912G>T | Intron (SNP) | VAF 39/591 reads (7%) | called by muse, mutect2
- AL049777.1 | n.510+4439G>T | Intron (SNP) | VAF 27/252 reads (11%) | catalogued as rs772487066; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73831108 del T | 3'Flank (DEL) | VAF 54/203 reads (27%) | called by mutect2, pindel, varscan2
- AMPH | c.-9C>A | 5'UTR (SNP) | VAF 51/323 reads (16%) | catalogued as rs1255429217; called by muse, mutect2, varscan2
- BMT2 | c.160+4361C>G | Intron (SNP) | VAF 37/283 reads (13%) | catalogued as rs17484277; called by muse, varscan2
- BRCA1 | c.4358-2693C>A | Intron (SNP) | VAF 22/369 reads (6%) | called by muse, mutect2
- C11orf98 | c.-16G>C | 5'UTR (SNP) | VAF 47/343 reads (14%) | catalogued as rs930886721, COSV104418721; called by muse, mutect2, varscan2
- C1orf105 | c.21+9387C>A | Intron (SNP) | VAF 60/276 reads (22%) | called by muse, mutect2, varscan2
- C9orf62 | n.194C>A | RNA (SNP) | VAF 37/317 reads (12%) | called by muse, mutect2, varscan2
- CACNB4 | c.699+292G>T | Intron (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- CELF4 | c.1165+22C>A | Intron (SNP) | VAF 42/419 reads (10%) | called by muse, mutect2
- CPPED1 | c.*11C>A | 3'UTR (SNP) | VAF 73/707 reads (10%) | called by muse, mutect2, varscan2
- CREB3L2 | c.319+5447A>T | Intron (SNP) | VAF 50/289 reads (17%) | called by muse, mutect2, varscan2
- DAP | c.*100G>T | 3'UTR (SNP) | VAF 77/526 reads (15%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2300G>C | 3'UTR (SNP) | VAF 24/227 reads (11%) | called by muse, mutect2, varscan2
- DENND10P1 | n.865T>C | RNA (SNP) | VAF 173/718 reads (24%) | called by muse, varscan2
- DENND10P1 | n.866G>T | RNA (SNP) | VAF 170/716 reads (24%) | called by muse, varscan2
- DNM1L | c.-60G>T | 5'UTR (SNP) | VAF 65/371 reads (18%) | called by muse, mutect2, varscan2
- DNM2 | c.162-41C>T | Intron (SNP) | VAF 24/282 reads (9%) | catalogued as rs143155298; called by muse, mutect2
- EBF3 | c.1759+1096G>T | Intron (SNP) | VAF 41/663 reads (6%) | called by muse, mutect2
- EFHB | chr3:19936187 C>A | 5'Flank (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2, varscan2
- EYA4 | c.1210-10T>C | Intron (SNP) | VAF 31/382 reads (8%) | called by muse, mutect2
- HAUS3 | c.*3546G>T | 3'UTR (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- HIPK1 | c.3144+31G>T | Intron (SNP) | VAF 58/356 reads (16%) | catalogued as COSV100479531; called by muse, mutect2, varscan2
- IDUA | c.973-21A>T | Intron (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- KRT18P23 | chr22:44571436 C>A | 3'Flank (SNP) | VAF 75/545 reads (14%) | called by muse, mutect2, varscan2
- LMF1 | c.1530-1349G>T | Intron (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- MAP3K19 | c.22+1151G>T | Intron (SNP) | VAF 72/468 reads (15%) | called by muse, mutect2, varscan2
- MCF2L | c.846+34G>T | Intron (SNP) | VAF 24/108 reads (22%) | catalogued as rs375372948; called by mutect2, varscan2
- MGAM | c.4618+5558G>A | Intron (SNP) | VAF 86/350 reads (25%) | called by muse, mutect2, varscan2
- MIR544A | n.80A>T | RNA (SNP) | VAF 62/310 reads (20%) | called by muse, varscan2
- MIR7162 | chr10:30364788 C>A | 3'Flank (SNP) | VAF 43/660 reads (7%) | called by muse, mutect2
- MIR9-1HG | n.338C>T | RNA (SNP) | VAF 67/472 reads (14%) | called by muse, mutect2, varscan2
- MYBPC1 | c.104-15C>T | Intron (SNP) | VAF 80/880 reads (9%) | called by muse, mutect2
- NR2F2-AS1 | n.984A>T | RNA (SNP) | VAF 26/332 reads (8%) | called by muse, mutect2
- NRXN1 | c.3365-109814G>T | Intron (SNP) | VAF 74/1018 reads (7%) | called by muse, mutect2
- OR2W5 | n.658G>T | RNA (SNP) | VAF 61/1090 reads (6%) | catalogued as rs779047712; called by muse, mutect2
- OR2W5 | n.802C>A | RNA (SNP) | VAF 50/892 reads (6%) | called by muse, mutect2
- PDE6G | c.*47G>C | 3'UTR (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- PITX2 | c.390+221G>T | Intron (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- PSCA | c.*362G>T | 3'UTR (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.1855-3038A>G | Intron (SNP) | VAF 10/68 reads (15%) | catalogued as rs372555098; called by muse, mutect2, varscan2
- RTBDN | c.462+340A>T | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- SAXO2 | c.53+2788G>T | Intron (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- SLC16A12 | c.*2459T>C | 3'UTR (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- SLC3A1 | c.766-390G>A | Intron (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- SNRPN | c.-370G>T | 5'UTR (SNP) | VAF 48/500 reads (10%) | called by muse, mutect2
- SOX6 | c.445+458G>C | Intron (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034654 G>T | 3'Flank (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- SSPOP | n.2071C>A | RNA (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.6239C>T | RNA (SNP) | VAF 35/293 reads (12%) | catalogued as rs746263180; called by muse, mutect2, varscan2
- STAT3 | c.1366-26C>G | Intron (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- TBC1D19 | c.-34G>T | 5'UTR (SNP) | VAF 82/512 reads (16%) | called by muse, mutect2, varscan2
- TSPAN32 | c.354+513C>A | Intron (SNP) | VAF 52/214 reads (24%) | called by muse, mutect2
- UBALD2 | c.-16del | 5'UTR (DEL) | VAF 28/178 reads (16%) | called by mutect2, pindel, varscan2
- UBBP4 | n.426G>T | RNA (SNP) | VAF 50/239 reads (21%) | catalogued as rs1466959789; called by muse, mutect2
- VAPB | c.*1665G>T | 3'UTR (SNP) | VAF 159/594 reads (27%) | called by muse, mutect2, varscan2
- VIM | c.1229+40C>A | Intron (SNP) | VAF 98/493 reads (20%) | called by muse, mutect2, varscan2
- VLDLR | c.*51C>A | 3'UTR (SNP) | VAF 20/248 reads (8%) | called by muse, mutect2
- XKR4 | c.806+60920C>A | Intron (SNP) | VAF 15/405 reads (4%) | called by muse, mutect2
